Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5738, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5738-01A (Primary Tumor).

CGA-CH-5738

Diagnosis

Prostatectomy preparation with infiltration of a moderately differentiated adenocarcinoma of the prostate on both sides. Maximum diameter of a single tumor focus: 2.1 cm.
No identifiable invasion of the vessels.

Tumor-free and regular seminal vesicles and seminal ducts.

Tumor in contact with (artefactual, yellow-labeled) preparation margin, other (genuine) preparation margins tumor-free.

Tumor classification: pT2c pNX, L0, V0; Gleason 3+3 = 6 (less than 5% Gleason 4 as tertiary Gleason score).

Source: NCI Genomic Data Commons file 5fa7964d-ba1f-4d09-85a3-b496a3e8793b (TCGA-CH-5738.3E17E46C-0C96-4930-B8AC-7ACEE8D40750.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).